Gene-level copy-number profile of tumor specimen C3L-01889-01 from CPTAC case C3L-01889, project CPTAC-3 (Bronchus and lung — Adenomas and Adenocarcinomas). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Lung, NOS; AJCC pathologic stage: Stage IB; Tumor grade: G2; Age at diagnosis: 71.7 years (26,205 days).
Specimen C3L-01889-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Lung; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 3239c7f2-ea9a-4b53-8804-5fcf91475a25.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator C3L-01889-31 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,230 have no estimate.
https://portal.gdc.cancer.gov/files/3a5c69b1-373a-4c60-b9bc-ca769d117116

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 3; copy number 2: 4,958; copy number 3: 196; copy number 4: 48,174; copy number 5: 686; copy number 6: 3,121; copy number 7: 155; copy number 8: 477; copy number 9: 179; copy number 10: 253; copy number 11: 92; copy number 12: 37; copy number 13: 62.

Homozygous deletions (total copy number 0; autosomes only): 3 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr19:20,416,514–20,571,095, 3 genes (within-gene range 0–2): BNIP3P22, AC008554.1, BNIP3P23.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 623 genes in 16 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr9:61,642,383–61,662,690, 2 genes, copy number 9: Y_RNA, AL935212.1.
- chr12:64,759,484–66,343,643, 41 genes, copy number 13: TBC1D30, AC078815.1, AC025262.3, RPL7P39, LINC02389, LINC02231, RNU6ATAC42P, AC135895.1, WIF1, RNU6-166P, APOOP3, LEMD3, AC026124.2, MSRB3, AC026124.1, KRT18P60, AC025419.1, AC090023.1, LINC02454, AC090023.2, PCNPP3, RPSAP52, HMGA2, AC107308.1, HMGA2-AS1, AC090673.1, MIR6074, LINC02425, RPL21P18, RNA5SP362, LLPH, AC078927.1, LLPH-DT, TMBIM4, IRAK3, RBMS1P1, MIR6502, AC078889.1, PDCL3P7, RN7SKP166, HELB.
- chr12:69,643,360–73,846,188, 52 genes, copy number 9–11: BEST3, AC025263.3, AC025263.1, RAB3IP, AC025263.2, MYRFL, PRANCR, AC078922.1, LINC02821, AC092881.2, CNOT2, AC092881.1, KCNMB4, RNU4-65P, AC025569.1, PTPRB, AC083809.1, PTPRR, FAHD2P1, Y_RNA, AC123905.1, AC025575.1, AC025575.2, TSPAN8, LGR5, AC090116.1, AC078860.3, ZFC3H1, AC078860.1, THAP2, AC073612.1, TMEM19, AC011601.1, RAB21, AC089984.1, AC089984.2, TBC1D15, MRS2P2, TPH2, AC090109.1, TRHDE, TRHDE-AS1, H3P35, CHCHD3P2, AC133480.1, AC090503.2, LINC02444, AC090503.1, AC087879.1, RNU6-1012P, LINC02445, U8.
- chr12:81,868,368–81,998,962, 3 genes, copy number 9: AC091515.1, LINC02426, AC011602.1.
- chr12:130,024,493–130,716,281, 19 genes, copy number 9: AC055717.2, LINC02418, AC135388.1, LINC02419, AC026336.4, AC026336.3, FZD10-AS1, AC026336.5, FZD10, AC026336.1, AC026336.2, PIWIL1, AC127071.2, AC127071.3, RIMBP2, AC063926.1, AC063926.3, AC063926.2, AC095350.1.
- chr12:132,489,551–133,238,549, 43 genes, copy number 10: FBRSL1, AC131212.3, AC131212.2, MIR6763, AC131212.1, LRCOL1, P2RX2, AC131212.4, POLE, PXMP2, AC135586.2, PGAM5, RNA5SP379, ANKLE2, AC135586.1, GOLGA3, CHFR, RPS11P5, RNU6-327P, AC127070.4, AC127070.1, AC127070.3, AC127070.2, ZNF605, NANOGNBP2, ZNF26, RNU4ATAC12P, ZNF84-DT, PTP4A1P2, ZNF84, AC073911.1, AC073911.2, ZNF140, ZNF891, AC026786.2, RPL23AP67, ZNF10, AC026786.1, ZNF268, AC226150.1, ANHX, RNU6-717P, Y_RNA.
- chr14:18,889,084–18,945,139, 5 genes, copy number 9: NEK2P1, NF1P7, MED15P1, AL929601.1, AL929601.2.
- chr17:26,981,694–28,022,464, 41 genes, copy number 9: AC069061.1, AC069061.2, PDLIM1P3, GTF2IP6, VN1R71P, TUFMP1, AC129926.1, RPL34P31, RPS16P8, AC026254.1, MIR4522, WSB1, AC026254.2, SYPL1P2, AC090615.1, TBC1D3P5, KSR1, AC069366.2, AC069366.1, ITM2BP1, AC015688.4, AC015688.6, LGALS9, NOS2P1, AC015688.3, AC015688.5, CPDP1, AC015688.2, AC015688.1, AC130289.1, AC130289.2, LGALS9DP, NOS2, AC005697.1, AC005697.2, LYRM9, LINC01992, AC005697.3, AC090287.1, AC090287.2, SNORA70.
- chr17:47,694,081–48,123,601, 28 genes, copy number 10: TBKBP1, TBX21, OSBPL7, MRPL10, LRRC46, SCRN2, SP6, AC018521.3, AC018521.7, AC018521.5, SP2, SP2-AS1, AC018521.6, PNPO, AC018521.1, AC018521.2, PRR15L, CDK5RAP3, AC018521.4, COPZ2, MIR152, NFE2L1-DT, NFE2L1, AC004477.1, AC004477.2, CBX1, RNU6-1201P, SNX11.
- chr17:48,185,938–48,204,529, 2 genes, copy number 10 (within-gene range 2–10): SKAP1-AS1, RNU6-1152P.
- chr17:48,713,730–51,260,163, 133 genes, copy number 9–12 (broad region; genes not listed).
- chr17:63,819,433–64,468,643, 30 genes, copy number 11–13: FTSJ3, PSMC5, SMARCD2, TCAM1P, CSH2, GH2, AC040958.1, CSH1, AC127029.1, CSHL1, GH1, AC127029.3, CD79B, SCN4A, AC127029.2, PRR29-AS1, PRR29, ICAM2, ERN1, AC005803.1, SNHG25, SNORD104, AC025362.1, SNORA50C, TEX2, RPL31P57, PECAM1, Y_RNA, AC234063.1, MILR1.
- chr17:66,197,693–73,092,712, 120 genes, copy number 10–11 (within-gene range 8–11) (broad region; genes not listed).
- chr17:74,043,452–75,879,546, 91 genes, copy number 10–13 (broad region; genes not listed).
- chr17:79,089,345–79,516,148, 1 gene, copy number 11 (within-gene range 2–11): RBFOX3.
- chr17:79,598,032–79,926,725, 12 genes, copy number 11: AC233701.1, MIR4739, LINC02078, ENPP7, CBX2, CBX8, AC100791.2, LINC01977, CBX4, AC100791.1, LINC01979, LINC01978.

Autosomal genes at a single copy (total copy number 1): 0. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
